Somatic mutation profile of tumor specimen TCGA-G4-6626-01A (aliquot TCGA-G4-6626-01A-11D-1771-10) from TCGA case TCGA-G4-6626, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-G4-6626-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ec0d79d-7c2d-4bb8-86d0-822acd67de1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6626-10A (Blood Derived Normal), aliquot TCGA-G4-6626-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78696241-a113-4bde-9be1-6d16238ca15f

The open-access MAF lists 145 somatic variants for this specimen: 101 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 41, Nonsense Mutation 7, In Frame Del 3, Intron 2, Splice Site 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 290/359 reads (81%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 39/103 reads (38%) | catalogued as rs201320564, CM050557; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 45/75 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AADACL2 | c.173A>T p.Y58F | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV62932512; called by muse, mutect2, varscan2
- ABCA2 | c.859C>A p.Q287K (on ENST00000614293; = p.Q257K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV99686639; called by muse, mutect2, varscan2
- ADAMTS15 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1264231152, COSV54509849; called by muse, mutect2, varscan2
- ALG5 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 121/289 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs544999445, COSV53507460; called by muse, mutect2, varscan2
- ALPK3 | c.5113C>T p.R1705W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs143300163; ClinVar: uncertain significance; called by muse, mutect2
- AMER1 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1179031603, COSV57654693; called by muse, mutect2, varscan2
- ARF5 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.189); catalogued as rs760826467, COSV50002087; called by muse, mutect2, varscan2
- ARID3B | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1195324733, COSV60556972; called by muse, mutect2, varscan2
- ATP8B1 | c.3015G>T p.Q1005H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52180395; called by mutect2, varscan2
- BRWD3 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 105/141 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV64753831; called by muse, mutect2, varscan2
- BTBD7 | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54139158, COSV54139859; called by muse, mutect2, varscan2
- CAND2 | c.2113G>A p.E705K (on ENST00000456430 / NM_001162499.2; = p.E612K on NM_012298.3) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs747135974, COSV55994854; called by muse, mutect2, varscan2
- CENPE | c.4229A>T p.K1410I | Missense Mutation (SNP) | VAF 637/1097 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV54390562; called by muse, mutect2, varscan2
- CHST2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58885568; called by muse, mutect2, varscan2
- COL19A1 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59589088; called by muse, mutect2, varscan2
- COL9A3 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs562245450, COSV59652769; called by muse, mutect2, varscan2
- CSMD1 | c.5887C>T p.R1963C (on ENST00000520002; = p.R1962C on NM_033225.6) | Missense Mutation (SNP) | VAF 117/234 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100141828, COSV100142573; called by muse, mutect2, varscan2
- CSTF3 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as COSV60614640; called by muse, mutect2, varscan2
- CTAG2 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs200770651, COSV55995878, COSV55996878, COSV99909244; called by muse, mutect2
- CTRC | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 75/112 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772024986, CM132130, COSV65621326; called by muse, mutect2, varscan2
- DAB2 | c.1833G>C p.M611I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV100297718; called by muse, mutect2
- DCTN4 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs200145293; called by muse, mutect2, varscan2
- DNAJC10 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as rs776207150, COSV51137461; called by muse, mutect2, varscan2
- EDC4 | c.3424C>T p.R1142W | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs755399568, COSV59303431; called by muse, mutect2, varscan2
- FAM47B | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1229137762, COSV61456239; called by muse, mutect2, varscan2
- FAM83C | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); catalogued as rs138265873; called by muse, mutect2, varscan2
- FBXW8 | c.1075C>T p.R359C (on ENST00000309909; = p.R397C on NM_012174.1) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777410294, COSV59303634; called by muse, mutect2, varscan2
- FCSK | c.2935C>G p.L979V | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55375753; called by muse, mutect2, varscan2
- FMO1 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV61447902; called by muse, mutect2, varscan2
- GALNT17 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs751565301, COSV61145992; called by muse, mutect2, varscan2
- GEMIN5 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 109/216 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1287462108, COSV53565106; called by muse, mutect2, varscan2
- GIGYF1 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs767907287, COSV51946933; called by muse, mutect2, varscan2
- GPR87 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as rs765905861, COSV53464477; called by muse, mutect2, varscan2
- GRIN2A | c.3722G>A p.R1241Q | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.532); catalogued as rs886042648, COSV58022353; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GZMB | c.736C>A p.R246S | Missense Mutation (SNP) | VAF 309/724 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99362144; called by muse, mutect2, varscan2
- HECW2 | c.1015C>A p.L339I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.629); catalogued as COSV53674712; called by muse, mutect2, varscan2
- HIVEP2 | c.4808G>A p.R1603Q | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs748022954, COSV50016791; called by muse, mutect2, varscan2
- INPPL1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV53355140; called by muse, mutect2, varscan2
- IRX2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV57413819; called by muse, mutect2, varscan2
- ITGAL | c.2986G>A p.V996M | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs372886251, COSV63322890; called by muse, mutect2, varscan2
- KCNH1 | c.2680G>A p.V894M (on ENST00000271751 / NM_172362.3; = p.V867M on NM_002238.4) | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.026); catalogued as rs371256167; called by muse, mutect2, varscan2
- KIAA1549 | c.851G>T p.S284I | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV54328988; called by muse, mutect2, varscan2
- KIF1A | c.4567C>T p.R1523W (on ENST00000320389 / NM_001379639.1; = p.R1515W on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs368124753; called by muse, mutect2, varscan2
- KIF5A | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1012819766, CM152455, COSV54059248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHDC3 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as COSV55065781; called by muse, mutect2, varscan2
- KLHL25 | c.787A>T p.K263* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as COSV61996562; called by muse, mutect2, varscan2
- KPRP | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs1454934158, COSV64220960; called by muse, mutect2, varscan2
- KRTAP27-1 | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 46/81 reads (57%) | catalogued as COSV67001683; called by muse, mutect2, varscan2
- LCE1E | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV64219993; called by muse, mutect2, varscan2
- MADD | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs140505071; called by muse, mutect2, varscan2
- MED13 | c.1040A>G p.K347R | Missense Mutation (SNP) | VAF 306/387 reads (79%) | SIFT tolerated (0.14); PolyPhen benign (0.193); catalogued as rs374567495; called by muse, mutect2, varscan2
- MLEC | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57330402; called by muse, mutect2
- NACC2 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs940690838, COSV53199274; called by mutect2, varscan2
- NEFM | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs949862142, COSV55331632, COSV55335031; called by muse, mutect2, varscan2
- NEUROD6 | c.995A>G p.N332S | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as COSV51773527; called by muse, mutect2, varscan2
- NR1D2 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs1384626966, COSV56990936; called by muse, mutect2, varscan2
- OBSCN | c.10856T>A p.L3619H | Missense Mutation (SNP) | VAF 107/351 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99470818; called by muse, mutect2, varscan2
- OR51T1 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59028145; called by muse, mutect2, varscan2
- OR52K1 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56904800; called by muse, mutect2, varscan2
- OR5R1 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV56573758; called by muse, mutect2, varscan2
- PARP3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.314); catalogued as COSV67169005; called by muse, mutect2, varscan2
- PCDHGA5 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV53918706; called by muse, mutect2, varscan2
- PEX5L | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs188814073; called by muse, mutect2, varscan2
- PGBD5 | c.1121C>T p.A374V (on ENST00000525115; = p.A443V on NM_001258311.2) | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs1476510143, COSV58413927; called by muse, mutect2, varscan2
- PKHD1 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs375547868; called by muse, mutect2, varscan2
- PPFIA2 | c.2863C>T p.R955* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as rs1238754403, COSV61019331; called by muse, mutect2, varscan2
- RIC8B | c.1448C>G p.P483R | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62693542, COSV62697235; called by muse, mutect2
- RRBP1 | c.3604G>A p.E1202K (on ENST00000377813 / NM_001365613.2; = p.E769K on NM_004587.3) | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55709055; called by muse, mutect2, varscan2
- SH3BP4 | c.2134G>A p.G712S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60646541; called by muse, mutect2, varscan2
- SLC25A23 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.376); catalogued as rs748515868, COSV51197391; called by muse, mutect2, varscan2
- SLC32A1 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54148434; called by muse, mutect2, varscan2
- SLC9A6 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 108/142 reads (76%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.557); catalogued as COSV65789083; called by muse, mutect2, varscan2
- SLC9A8 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); catalogued as rs144315631; called by muse, mutect2, varscan2
- SMCR8 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs757228832, COSV58176465; called by muse, mutect2, varscan2
- SNX17 | c.848A>G p.E283G | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV52010888; called by muse, mutect2, varscan2
- SOAT2 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV56858000; called by muse, mutect2, varscan2
- SSBP3 | c.853G>A p.A285T (on ENST00000371320 / NM_145716.4; = p.A265T on NM_018070.5) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs1018009964, COSV58890055; called by muse, mutect2, varscan2
- STAC | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs769980894, COSV56213071; called by muse, mutect2, varscan2
- TCF21 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs750251328, COSV52819694; called by muse, mutect2, varscan2
- TRIM73 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99303020, COSV99303028; called by muse, mutect2, varscan2
- TSHR | c.2002C>A p.P668T | Missense Mutation (SNP) | VAF 99/301 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53332123; called by muse, mutect2, varscan2
- TTC38 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 25/41 reads (61%) | catalogued as rs754609621, COSV66845190; called by muse, mutect2, varscan2
- UNC80 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99778025; called by muse, mutect2, varscan2
- UPF1 | c.1837G>A p.A613T (on ENST00000599848 / NM_001297549.2; = p.A602T on NM_002911.4) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.169); catalogued as rs1334288478, COSV53201536; called by muse, mutect2, varscan2
- USP42 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.301); catalogued as COSV60364600; called by muse, mutect2, varscan2
- WARS1 | c.539C>A p.T180K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV59927803; called by muse, mutect2, varscan2
- ZNF117 | c.301A>T p.M101L | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99275072; called by muse, mutect2, varscan2
- ZNF366 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59219197; called by muse, mutect2, varscan2
- ZNF585A | c.397G>T p.A133S (on ENST00000292841 / NM_001288800.2; = p.A78S on NM_152655.3) | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs533790578, COSV53062969, COSV53067130; called by muse, mutect2, varscan2
- ZNF789 | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV58875253; called by muse, mutect2, varscan2
- ZNF99 | c.1904C>A p.T635N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV68056825; called by muse, mutect2, varscan2
- BBS12 | c.1896_1898del p.S634del | In Frame Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- IGHG1 | c.856T>C p.S286P | Missense Mutation (SNP) | VAF 123/570 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RNF111 | c.2227_2228del p.Q743Efs*6 | Frame Shift Del (DEL) | VAF 41/85 reads (48%) | called by pindel, varscan2
- SDHA | c.1909-12_1945delinsTCTTTTCAAGGTCACTCTGGAATATAGACCCGTAATCGACAAAAC p.X637_splice | Splice Site (DEL) | VAF 19/215 reads (9%) | called by pindel, varscan2*
- STK17A | c.281A>G p.K94R | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2
- TOR1A | c.984_986del p.Y330del | In Frame Del (DEL) | VAF 48/102 reads (47%) | called by pindel, varscan2
- TRMT11 | c.956_958del p.R319del | In Frame Del (DEL) | VAF 22/124 reads (18%) | called by pindel, varscan2
- ABCA13 | c.11667G>A p.T3889= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as rs367685852; called by muse, mutect2, varscan2
- ANKS1A | c.2457C>T p.L819= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs766999402, COSV64464791; called by muse, mutect2, varscan2
- ANO1 | c.1227G>A p.T409= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs374544085; called by muse, mutect2, varscan2
- ARHGEF11 | c.258C>T p.G86= | Silent (SNP) | VAF 84/226 reads (37%) | catalogued as rs751727111, COSV63812653; called by muse, mutect2, varscan2
- BDKRB1 | c.1050C>T p.F350= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV53705790; called by muse, mutect2, varscan2
- COL22A1 | c.264G>A p.T88= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1195461317, COSV57347850; called by muse, mutect2, varscan2
- CPSF1 | c.1443C>T p.G481= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs559929747, COSV62942497; called by muse, mutect2, varscan2
- CSMD3 | c.144C>T p.N48= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as rs781294011, COSV52324576; called by muse, mutect2, varscan2
- DENND2C | c.555C>T p.Y185= | Silent (SNP) | VAF 43/160 reads (27%) | catalogued as rs374406910; called by muse, mutect2, varscan2
- DSG3 | c.2748C>T p.V916= | Silent (SNP) | VAF 84/116 reads (72%) | catalogued as COSV57129825; called by muse, mutect2, varscan2
- EPHA3 | c.1011C>T p.N337= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs201113556, COSV60713386, COSV60728079; called by muse, mutect2, varscan2
- ESYT1 | c.501G>A p.P167= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as rs777826405, COSV57276558; called by muse, mutect2, varscan2
- FBXW11 | c.27C>T p.D9= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, varscan2
- HSH2D | c.279C>G p.P93= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV53739898; called by muse, mutect2, varscan2
- KIAA0319 | c.891G>A p.P297= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as rs767798827, COSV65501980; called by muse, mutect2, varscan2
- KIF2B | c.555C>T p.Y185= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs369155067, COSV52132496; called by muse, mutect2, varscan2
- MOSPD3 | c.147C>T p.S49= | Silent (SNP) | VAF 127/335 reads (38%) | catalogued as COSV99774855; called by muse, mutect2, varscan2
- MUC2 | c.420C>T p.R140= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as rs759542520; called by muse, mutect2, varscan2
- MXRA5 | c.117C>G p.V39= | Silent (SNP) | VAF 170/219 reads (78%) | catalogued as COSV54251101, COSV99477539; called by muse, varscan2
- MYOC | c.36G>A p.G12= | Silent (SNP) | VAF 60/130 reads (46%) | catalogued as COSV50679290; called by muse, mutect2, varscan2
- NALCN | c.1116C>T p.R372= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs200582234, COSV51943338; called by muse, mutect2, varscan2
- PBX2 | c.1089C>T p.N363= | Silent (SNP) | VAF 19/203 reads (9%) | catalogued as rs147090639; called by muse, mutect2, varscan2
- PIK3CG | c.849C>T p.G283= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs766973241, COSV63252242; called by muse, mutect2, varscan2
- PLAAT2 | c.75C>T p.A25= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV55375656; called by muse, mutect2, varscan2
- PTPRB | c.3291C>T p.S1097= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV54253921; called by muse, mutect2, varscan2
- RORB | c.468C>T p.H156= (on ENST00000396204 / NM_001365023.1; = p.H145= on NM_006914.4) | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs1452877829, COSV65340202; called by muse, mutect2, varscan2
- RPE65 | c.501T>C p.D167= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV52013137; called by muse, mutect2, varscan2
- SEC24B | c.1386C>A p.G462= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV54507006; called by muse, mutect2, varscan2
- SLC6A3 | c.1266C>T p.S422= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs1246818027, COSV54364542, COSV54366912; called by muse, mutect2, varscan2
- SRRT | c.1551G>A p.V517= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV53821654; called by muse, mutect2, varscan2
- STN1 | c.144G>A p.L48= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs775545391, COSV56546172; called by muse, mutect2, varscan2
- TNR | c.1710C>T p.Y570= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs746969510, COSV54899996; called by muse, mutect2, varscan2
- TPPP | c.255G>A p.V85= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV62193694; called by muse, mutect2, varscan2
- TRPM6 | c.3303G>T p.L1101= | Silent (SNP) | VAF 91/198 reads (46%) | catalogued as COSV62508877; called by muse, mutect2, varscan2
- UTP20 | c.2691C>T p.P897= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV55385666; called by muse, mutect2, varscan2
- WDR49 | c.285G>A p.L95= (on ENST00000308378 / NM_001366158.1; = p.L436= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as COSV57718191; called by muse, mutect2, varscan2
- WEE2 | c.1347G>T p.P449= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV66880135; called by muse, mutect2, varscan2
- ZBTB39 | c.2118G>A p.A706= | Silent (SNP) | VAF 33/169 reads (20%) | catalogued as rs369298043, COSV55629125; called by muse, mutect2, varscan2
- ZFHX4 | c.1128G>A p.P376= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs771819258, COSV51497063; called by muse, mutect2, varscan2
- ZNF304 | c.363G>A p.L121= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as rs1387825468, COSV56586593; called by muse, mutect2, varscan2
- ZNF311 | c.642C>T p.T214= | Silent (SNP) | VAF 59/152 reads (39%) | catalogued as COSV101014052; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668295 G>T | 5'Flank (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- OFCC1 | n.393-2950G>A | Intron (SNP) | VAF 54/195 reads (28%) | called by muse, mutect2, varscan2
- POLA1 | c.2947-21062C>T | Intron (SNP) | VAF 14/66 reads (21%) | catalogued as rs759976203, COSV66883518; called by muse, mutect2, varscan2
